Somatic mutation profile of tumor specimen TCGA-M7-A71Z-01A (aliquot TCGA-M7-A71Z-01A-12D-A32B-08) from TCGA case TCGA-M7-A71Z, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.4 years (22,785 days).
Specimen TCGA-M7-A71Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42506bc1-1c51-4578-9007-efb386e45843.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-M7-A71Z-10A (Blood Derived Normal), aliquot TCGA-M7-A71Z-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78dab59a-6025-4c6b-8a4e-c93196f4413c

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRI3BP | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs145269757; called by muse, mutect2, varscan2
- CLASP1 | c.3284C>T p.T1095M | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs773202450, COSV99757376; called by muse, mutect2, varscan2
- CRB1 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV66331151; called by muse, mutect2, varscan2
- EPHB1 | c.2594G>A p.R865Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751581569, COSV67654713; called by mutect2, varscan2
- F10 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs144711550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLIS1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754472609, COSV56557169; called by muse, mutect2, varscan2
- GPR179 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1451373621; called by muse, mutect2, varscan2
- GRM1 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs553512718, COSV51109088; called by muse, mutect2, varscan2
- GSDME | c.1232A>G p.Q411R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs961870587, COSV100742454; called by muse, mutect2, varscan2
- HIVEP2 | c.5857G>T p.V1953L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs376862866, COSV99175712; called by muse, mutect2, varscan2
- KCNA5 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99364233; called by muse, mutect2, varscan2
- LARS1 | c.315A>C p.K105N (on ENST00000394434 / NM_020117.11; = p.K78N on NM_016460.3) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); catalogued as COSV99198901; called by muse, mutect2, varscan2
- LRRIQ1 | c.2846dup p.N949Kfs*5 | Frame Shift Ins (INS) | VAF 32/90 reads (36%) | catalogued as rs1198982949; called by mutect2, pindel, varscan2
- MACF1 | c.3559C>G p.L1187V | Missense Mutation (SNP) | VAF 30/147 reads (20%) | catalogued as COSV100486629; called by muse, mutect2, varscan2
- NCOA2 | c.87C>T p.S29= | Splice Region (SNP) | VAF 7/50 reads (14%) | catalogued as rs1488656252, COSV101476060; called by muse, mutect2, varscan2
- PDE1C | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.797); catalogued as COSV100373971, COSV58510450; called by muse, mutect2, varscan2
- PSD4 | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 85/180 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); catalogued as COSV99831498; called by muse, mutect2, varscan2
- RYR2 | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1553328170, CM148846, COSV63697882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA7A | c.1945G>A p.A649T | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs757652732, COSV56090132; called by muse, mutect2, varscan2
- SLC19A2 | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99357151; called by muse, mutect2, varscan2
- SMCHD1 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1227032781, COSV55252896; called by muse, mutect2, varscan2
- TLN2 | c.4988G>T p.C1663F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100170153; called by muse, mutect2, varscan2
- UBXN4 | c.1219del p.S407Pfs*22 | Frame Shift Del (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD36 | c.33C>A p.T11= | Silent (SNP) | VAF 6/142 reads (4%) | catalogued as COSV101347550; called by muse, mutect2
- BCORL1 | c.2685C>T p.F895= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99501042; called by muse, mutect2
- OR5AR1 | c.573C>T p.D191= | Silent (SNP) | VAF 15/152 reads (10%) | catalogued as COSV100265819; called by muse, mutect2
- SSTR4 | c.507C>T p.G169= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as rs765345182, COSV54797552; called by muse, mutect2, varscan2
- UNC13C | c.1746G>A p.S582= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs377052322; called by muse, mutect2, varscan2
